Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ABJZ, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ABJZ-TTP1-A (Primary Tumor).

Material description

- A) Left lower lung, nodule
- B) Left lower lobe, lung
- C) Lower paratracheal lymph nodes
- D) Subcarinal lymph nodes
- E) Lymph nodes of pulmonary ligament
- F) Interlobar lymph nodes

ICD-0-3
adenocarcinoma, NOS 8140/3
Site: (L) lung, lower lobe C34.3

ICD-10
C34.32

hw
2/9/16

Macro description

A) Fragment of pulmonary parenchyma of 7.8 x 3.2 x 3 cm with visceral smooth e shining pleura (closed margin because of metal stitches)

When you cut, there is intraparenchymal neoformation, grayish, roundish, clear margins, hard-elastic compactness, bigger axis of 1,2 cm on which we do intraoperative examination (A1 intraoperative sample, A2-A3 neoformation)

13) Left lower lobe (lung), 16 x 14 x 5 cm (117 grams), with focally dusty and whitish pleura and with surgical injury attributable to nodulectomy

Pulmonary parenchyma doesn't present macroscopic alterations of significance.

We close off 10 peribronchial lymph nodes (B1 margin of bronco-vascular resection; B2 dusty and whitish pleura; B3 pulmonary parenchyma; B4-B7 peribronchial lymph nodes)

C) 2 yellow-blackish fragments of 0.5 and 0.9 cm of bigger axis, soft consistence

D) 2 white-grayish fragments of 0.4 and 0.8 cm of bigger axis, soft consistence

E) 1 white-grayish fragment of 0.8 cm of bigger axis, soft consistence

F) 1 yellow-brownish fragment of 0.6 cm of bigger axis, soft consistence

Micro description

Lung acinar adenocarcinoma (WHO 1999), poorly differentiated (G3) infiltrating. Visceral pleura, margin of bronchial and vascular resection unscathed from neoplasm.

Subpleural bullous emphysema associated with district fibrosis in the remaining pulmonary parenchyma. Histiocytosis of sinuses and black lung disease in every lymph node examined.

Intraoperative diagnosis of A (): adenocarcinoma

Staging

pTNM: pT1, N0

Source: NCI Genomic Data Commons file 5f46d0bc-4827-49d9-bed4-e3ac6ebd00ae (CDDP-ABJZ-TTP1.B79A197C-6A57-4821-829A-A17ABF216192.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).